TCGA case TCGA-IB-A6UG — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Alberta Health Services. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/45e48080-0b27-45f4-8149-1ae7e36c6933

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 65 years; Vital status: Dead; Days to death: 41 days; Cause of death: Not Cancer Related; Cause of death source: Medical Record.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 65.0 years (23,751 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 41 days; Sites of involvement: Pancreas Head; Tumor grade category: Four Tier.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 16; Lymph nodes tested: 19; Tumor largest dimension diameter: 3 cm.
   Treatment given: Treatment type: Whipple.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 41 days; Disease response: With Tumor.

Exposures
- Alcohol history: No; Alcohol intensity: Non-Drinker.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 33.75; Tobacco smoking onset year: 1968.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IB-A6UG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 180 mg.
  Slide TCGA-IB-A6UG-01A-03-TSC: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 35; Percent normal cells: 40; Percent necrosis: 0; Percent stromal cells: 35; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-IB-A6UG-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IB-A6UG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Method initial path diagnosis: Tissue Biopsy; Lymph nodes examined: Yes; Tumor status: With tumor; Cause of death: Other, non-malignant disease; Tobacco smoking history indicator: 2; Alcohol history documented: Yes; Diabetes diagnosis indicator: No; History chronic pancreatitis: No; Treatment outcome first course: Partial Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor; Cause of death: Other, non-malignant disease; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 41 days; disease-specific survival: no event (censored), 41 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 41 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IB-A6UG-01A-32D-A33S-01): tumor purity 0.22, ploidy 3.32, whole-genome doublings 1.
